Somatic mutation profile of tumor specimen ALCH-B1VE-TTR1-A (aliquot ALCH-B1VE-TTR1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B1VE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,076 days).
Specimen ALCH-B1VE-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36f4bd0a-5a9f-41c4-b251-9ec2561978c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VE-NB1-A (Blood Derived Normal), aliquot ALCH-B1VE-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22307e68-27de-40f0-a743-6bdc580a3f02

The open-access MAF lists 1,891 somatic variants for this specimen: 1,292 protein-altering or splice-affecting, 380 silent, 219 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,090, Silent 380, Intron 95, Nonsense Mutation 89, Splice Site 50, RNA 40, 3'UTR 34, Frame Shift Del 28, 5'UTR 25, Splice Region 20, 5'Flank 14, 3'Flank 11.

Variants (750 of 1,891; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs121913382, COSV58682685, COSV58683250; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SHH | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886042458, CM041838, CM094632, CM095888; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 76/144 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.21C>G p.S7R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV99446058; called by muse, mutect2, varscan2
- ABCB5 | c.1663C>A p.L555M (on ENST00000404938 / NM_001163941.2; = p.L110M on NM_178559.6) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328374; called by muse, mutect2, varscan2
- ABL2 | c.2734G>T p.G912C (on ENST00000502732 / NM_007314.4; = p.G897C on NM_005158.5) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as rs140629135; called by muse, mutect2, varscan2
- AC090517.4 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.251); catalogued as rs749272153; called by muse, mutect2, varscan2
- ACBD5 | c.1604G>T p.*535Lext*18 (on ENST00000375888 / NM_001352568.1; = p.*526Lext*18 on NM_145698.5 and 4 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV65518491; called by muse, mutect2, varscan2
- ACHE | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53814972; called by muse, mutect2, varscan2
- ACSM2A | c.1340G>T p.R447L (on ENST00000219054; = p.R368L on NM_001308169.2) | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV54586379; called by muse, varscan2
- ACSM2B | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs146841908, COSV61658598; called by muse, mutect2, varscan2
- ACTRT1 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs367847967, COSV64418970; called by muse, mutect2, varscan2
- ACTRT2 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs768291220, COSV65759034; called by muse, mutect2, varscan2
- ADAMTS20 | c.2550G>T p.W850C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67134904; called by muse, mutect2, varscan2
- ADAMTS3 | c.2465A>G p.Y822C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770065467; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV52827179; called by muse, mutect2, varscan2
- ADGRG4 | c.5792C>A p.S1931Y | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV99795171; called by muse, varscan2
- AHNAK2 | c.10952C>A p.S3651* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV60911545; called by muse, mutect2, varscan2
- AHNAK2 | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1253216001; called by mutect2, varscan2
- AKAIN1 | c.128G>C p.R43P | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV71420475; called by muse, mutect2, varscan2
- AKAP11 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1221411587; called by muse, mutect2, varscan2
- ALAD | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52959823; called by muse, mutect2, varscan2
- ALB | c.1428T>C p.Y476= | Splice Region (SNP) | VAF 16/72 reads (22%) | catalogued as rs757476866, COSV55737675; called by muse, mutect2, varscan2
- ALS2CL | c.2825G>T p.R942L | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV100015192; called by muse, mutect2, varscan2
- AMER3 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV58467681; called by muse, mutect2, varscan2
- AMY1C | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765919741, COSV64407108; called by muse, mutect2, varscan2
- ANAPC4 | c.2129A>T p.H710L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as COSV59544848; called by muse, mutect2, varscan2
- ANKRD26 | c.2563G>T p.V855F | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV65774652; called by muse, mutect2, varscan2
- ANKRD30A | c.1151C>T p.A384V (on ENST00000611781; = p.A328V on NM_052997.2) | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.483); catalogued as rs770792408; called by muse, mutect2, varscan2
- APBA3 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs765983166; called by muse, mutect2, varscan2
- ARFGEF3 | c.5457C>A p.H1819Q | Missense Mutation (SNP) | VAF 77/134 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV52463623; called by muse, mutect2, varscan2
- ARHGAP31 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51794256; called by muse, mutect2, varscan2
- ARHGEF11 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1265248620; called by muse, mutect2, varscan2
- ASPM | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs761690546; called by muse, mutect2, varscan2
- ATP1B4 | c.671G>A p.R224H (on ENST00000218008 / NM_001142447.3; = p.R220H on NM_012069.5) | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376908557, COSV54312056; called by muse, mutect2, varscan2
- ATP6V1F | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.244); catalogued as rs1405868597; called by muse, mutect2, varscan2
- BAAT | c.211A>T p.M71L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs765262834; called by mutect2, varscan2
- BACH2 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747189218; called by muse, mutect2, varscan2
- BPIFB1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV53609745; called by muse, mutect2, varscan2
- BRF1 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100527081; called by muse, mutect2, varscan2
- BRINP2 | c.907T>A p.F303I | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64180580; called by muse, mutect2, varscan2
- BRINP3 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100818417, COSV100819618; called by muse, mutect2, varscan2
- C1QTNF4 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100209256; called by muse, mutect2, varscan2
- C2orf81 | c.488dup p.V164Rfs*58 | Frame Shift Ins (INS) | VAF 14/70 reads (20%) | catalogued as rs773631384; called by mutect2, pindel, varscan2
- C6orf118 | c.312G>T p.R104S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV57815204; called by muse, mutect2, varscan2
- C8orf34 | c.1555G>C p.A519P | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV61381291; called by muse, mutect2, varscan2
- CA2 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1453620373; called by muse, mutect2, varscan2
- CABIN1 | c.4702G>T p.A1568S | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV54079306; called by muse, mutect2, varscan2
- CACNA1C | c.5320G>A p.A1774T | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.086); catalogued as rs767425352, COSV59736148; called by muse, mutect2, varscan2
- CADM3 | c.685del p.V229Ffs*8 (on ENST00000368125 / NM_001127173.3; = p.V263Ffs*8 on NM_021189.5) | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as COSV63687001; called by pindel, varscan2
- CADPS | c.3106C>A p.P1036T | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs868827229; called by muse, mutect2, varscan2
- CADPS | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51892283, COSV99337318; called by muse, mutect2, varscan2
- CASP7 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61882927; called by muse, mutect2, varscan2
- CASR | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99949562; called by muse, mutect2, varscan2
- CATSPERE | c.366G>T p.W122C | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835365; called by muse, mutect2, varscan2
- CCDC168 | c.2809G>A p.V937I | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1412245787; called by muse, mutect2, varscan2
- CCER1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV62647525; called by muse, mutect2, varscan2
- CCHCR1 | c.335G>C p.R112P | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66161201, COSV66161514; called by muse, varscan2
- CCIN | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV58724854; called by muse, mutect2, varscan2
- CD1C | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV63806924; called by muse, mutect2, varscan2
- CDH2 | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 25/139 reads (18%) | catalogued as COSV52296678; called by muse, mutect2, varscan2
- CDH9 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50305218; called by muse, mutect2, varscan2
- CDK8 | c.653G>T p.W218L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1193622051; called by muse, mutect2, varscan2
- CENPF | c.3975G>T p.R1325S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100871379; called by muse, mutect2, varscan2
- CEP78 | c.1024A>G p.I342V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs765160106; called by muse, mutect2, varscan2
- CHGB | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); catalogued as rs959112926; called by muse, varscan2
- CHM | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63303198; called by muse, mutect2, varscan2
- CHRNA2 | c.215G>C p.R72P | Missense Mutation (SNP) | VAF 72/120 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs201922955, COSV53558436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIC | c.2123G>C p.R708T | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV50549729; called by muse, mutect2, varscan2
- CLIC5 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.018); catalogued as rs1299654748; called by muse, mutect2, varscan2
- CLVS2 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV51561523, COSV51566135; called by muse, mutect2, varscan2
- COL15A1 | c.1680G>T p.Q560H | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV66644249; called by muse, mutect2, varscan2
- COL1A2 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 65/367 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51953108; called by muse, mutect2, varscan2
- COL1A2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 93/192 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM062543; called by muse, mutect2, varscan2
- COL1A2 | c.1801G>T p.G601C | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM011304, COSV51952372; called by muse, mutect2, varscan2
- COL21A1 | c.1283G>C p.G428A | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.138); catalogued as COSV55182404; called by muse, mutect2, varscan2
- COL22A1 | c.3072G>C p.K1024N | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV57360051; called by muse, mutect2, varscan2
- COL6A1 | c.1515G>C p.M505I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV62614872; called by muse, mutect2, varscan2
- COL6A3 | c.5525G>T p.G1842V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM1413880, COSV55101483; called by muse, mutect2, varscan2
- CPED1 | c.2542C>A p.L848I | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1278152351, COSV60002748, COSV60004550; called by muse, mutect2, varscan2
- CPS1 | c.1688C>A p.P563Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV51810138; called by muse, mutect2, varscan2
- CSMD2 | c.5729C>A p.P1910Q | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); catalogued as COSV53910319; called by muse, mutect2, varscan2
- CSMD3 | c.7897G>T p.G2633W (on ENST00000297405 / NM_001363185.1; = p.G2529W on NM_052900.3) | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843215; called by muse, mutect2, varscan2
- CSMD3 | c.6499G>C p.V2167L (on ENST00000297405 / NM_001363185.1; = p.V2063L on NM_052900.3) | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV52275604; called by muse, mutect2, varscan2
- CSMD3 | c.3058C>G p.R1020G (on ENST00000297405 / NM_001363185.1; = p.R916G on NM_052900.3) | Missense Mutation (SNP) | VAF 104/228 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as COSV99827650; called by muse, mutect2, varscan2
- CSN2 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as COSV100778826; called by mutect2, varscan2
- CSPG5 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53131454; called by muse, mutect2, varscan2
- CTNNA2 | c.2713T>C p.S905P (on ENST00000402739 / NM_001282597.3; = p.S857P on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.868); catalogued as rs757086633, COSV100561669; called by muse, mutect2, varscan2
- CTNND2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs1278093121, COSV58898815; called by muse, mutect2, varscan2
- CUBN | c.6124G>A p.G2042R | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746491117; called by muse, mutect2, varscan2
- CUL3 | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 27/115 reads (23%) | catalogued as COSV52368270; called by muse, mutect2, varscan2
- CYFIP1 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753341549; called by muse, mutect2
- CYLC1 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.354); catalogued as rs773438086, COSV61413104; called by muse, mutect2, varscan2
- CYP1A1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.932); catalogued as rs375219443; called by mutect2, varscan2
- CYP2F1 | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58527075; called by muse, mutect2, varscan2
- DCAF11 | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100386937, COSV58110004; called by muse, mutect2, varscan2
- DCDC1 | c.658G>C p.G220R | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100663334; called by muse, mutect2, varscan2
- DGKI | c.2497G>T p.D833Y | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99938477; called by muse, mutect2, varscan2
- DGKK | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV65709735; called by muse, mutect2, varscan2
- DKK2 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99569347; called by muse, varscan2
- DNAH3 | c.8813C>A p.A2938D | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV54527101; called by muse, mutect2, varscan2
- DOCK3 | c.3460G>A p.E1154K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs762516944, COSV56535208; called by muse, varscan2
- DPP3 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV100855407, COSV64756305; called by muse, mutect2, varscan2
- DUSP23 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63660472; called by muse, mutect2, varscan2
- EML6 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62869325; called by muse, mutect2, varscan2
- EP400 | c.1675G>C p.G559R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); catalogued as COSV100200445, COSV100200737; called by muse, mutect2, varscan2
- EPHA3 | c.2927C>A p.S976* | Nonsense Mutation (SNP) | VAF 45/90 reads (50%) | catalogued as COSV60727126; called by muse, mutect2, varscan2
- EPHB6 | c.245C>A p.P82Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as COSV67420923; called by muse, mutect2, varscan2
- EREG | c.42G>T p.R14S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.01); catalogued as rs1239604549; called by muse, mutect2, varscan2
- ESR1 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52786522; called by muse, mutect2, varscan2
- EXT1 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV65479902; called by muse, mutect2, varscan2
- F13A1 | c.232C>A p.R78S | Missense Mutation (SNP) | VAF 91/185 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023370, COSV53554575, COSV53565368; called by muse, mutect2, varscan2
- F8 | c.1573G>T p.G525* | Nonsense Mutation (SNP) | VAF 74/177 reads (42%) | catalogued as CM108711, CM1414972; called by muse, mutect2, varscan2
- F8 | c.906G>C p.Q302H | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.913); catalogued as CD961976; called by muse, varscan2
- FAM135B | c.3091G>T p.V1031L | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs956298724; called by muse, mutect2, varscan2
- FAT3 | c.3045A>T p.K1015N | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV53098300; called by muse, mutect2, varscan2
- FBN3 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747885195; called by muse, mutect2, varscan2
- FBXL7 | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV61647016; called by muse, mutect2, varscan2
- FER1L6 | c.3815C>A p.P1272H | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101205736; called by muse, mutect2, varscan2
- FEV | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773550327; called by muse, mutect2, varscan2
- FGF21 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV55810608; called by muse, mutect2, varscan2
- FLG | c.6929C>A p.S2310Y | Missense Mutation (SNP) | VAF 231/361 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV100911687, COSV64239386; called by muse, mutect2, varscan2
- FLG | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 331/495 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748125717; called by muse, mutect2, varscan2
- FLNC | c.7030G>T p.A2344S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57956828; called by muse, mutect2, varscan2
- FRYL | c.6754C>T p.R2252C | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755564286; called by muse, mutect2, varscan2
- FSIP2 | c.12598G>C p.D4200H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV58098852; called by muse, varscan2
- GABRA4 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV51924431; called by muse, mutect2, varscan2
- GABRA5 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59479875, COSV59479912; called by muse, mutect2, varscan2
- GALNT13 | c.517T>G p.L173V | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs765363190; called by muse, varscan2
- GAP43 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 63/106 reads (59%) | catalogued as COSV59348582; called by muse, mutect2, varscan2
- GCNT1 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV65058625; called by muse, mutect2, varscan2
- GOLGA8O | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs565343702; called by mutect2, varscan2
- GPR101 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.111); catalogued as rs775145092; called by muse, mutect2, varscan2
- GPR89B | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 114/221 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs1409634730; called by muse, mutect2, varscan2
- GPRIN3 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as COSV60886498; called by muse, mutect2
- GRIA2 | c.573G>T p.M191I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52386581; called by muse, mutect2, varscan2
- GRIN3A | c.1558C>A p.L520M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62459830; called by muse, mutect2
- GSX2 | c.232G>C p.A78P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as COSV104400791; called by muse, mutect2, varscan2
- HCN1 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as COSV100298381, COSV57492101, COSV57537055; called by muse, mutect2, varscan2
- HEATR5B | c.1870C>A p.H624N | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs764605370; called by muse, mutect2, varscan2
- HGF | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55947201; called by muse, mutect2, varscan2
- HTR5A | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV55280821, COSV99840092; called by muse, varscan2
- HUWE1 | c.5230G>C p.E1744Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.062); catalogued as COSV53338229; called by muse, mutect2, varscan2
- IGHV3-11 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as rs367668334; called by muse, mutect2, varscan2
- IGLV4-69 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs775820038; called by muse, mutect2, varscan2
- IGSF22 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs201509265; called by muse, mutect2, varscan2
- IL13RA2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 24/160 reads (15%) | catalogued as COSV54563994; called by muse, mutect2, varscan2
- INHBA | c.575C>A p.A192D | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.213); catalogued as COSV54223288; called by muse, mutect2, varscan2
- INSYN2B | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.518); catalogued as COSV56972370; called by muse, mutect2, varscan2
- INSYN2B | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99910037; called by muse, mutect2, varscan2
- IPO8 | c.2353G>T p.V785F | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56244801; called by muse, mutect2, varscan2
- IQUB | c.301A>G p.M101V | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs777466154; called by muse, mutect2, varscan2
- ISLR2 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); catalogued as COSV62301881; called by muse, mutect2, varscan2
- ITLN1 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377093370; called by muse, mutect2, varscan2
- ITPR2 | c.7502G>A p.G2501E | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67269471, COSV67276318; called by muse, mutect2, varscan2
- KASH5 | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1300479714; called by muse, mutect2, varscan2
- KCNK6 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368898579; called by muse, mutect2
- KEAP1 | c.995del p.G332Afs*68 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as COSV50480137, COSV99407912; called by mutect2, pindel, varscan2
- KIAA1755 | c.1741C>A p.L581M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54076234; called by muse, mutect2, varscan2
- KIF2B | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV52135668; called by muse, mutect2, varscan2
- KIR3DL3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV52545631, COSV99399929; called by muse, mutect2, varscan2
- KLHL30 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as rs1007756444; called by muse, mutect2, varscan2
- KRTAP20-1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 60/146 reads (41%) | PolyPhen probably damaging (0.954); catalogued as rs769908331, COSV58167811; called by muse, mutect2, varscan2
- KRTAP4-11 | c.436del p.R146Afs*101 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as COSV66948487; called by mutect2, varscan2
- KRTAP4-2 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473798038; called by muse, mutect2, varscan2
- L1CAM | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100649030; called by muse, mutect2, varscan2
- LAMA1 | c.8821G>T p.G2941* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as rs754365125, COSV67543750; called by muse, mutect2, varscan2
- LAMA2 | c.6225C>A p.S2075R | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV70343844; called by muse, mutect2, varscan2
- LAMA4 | c.4420G>A p.G1474R (on ENST00000230538 / NM_001105206.3; = p.G1467R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57896525; called by muse, mutect2, varscan2
- LAMA4 | c.3879G>A p.M1293I (on ENST00000230538 / NM_001105206.3; = p.M1286I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1554329600, COSV57898237, COSV57905568; called by muse, mutect2, varscan2
- LAMA5 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV53360309; called by muse, mutect2, varscan2
- LIN7A | c.201+1G>A p.X67_splice | Splice Site (SNP) | VAF 77/216 reads (36%) | catalogued as COSV99692237; called by muse, mutect2, varscan2
- LRFN5 | c.922T>A p.C308S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53244360; called by muse, mutect2, varscan2
- LRFN5 | c.1632C>A p.F544L | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325035617, COSV53269334; called by muse, mutect2, varscan2
- LRRC37B | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs1391577583, COSV100496386; called by muse, mutect2, varscan2
- LRRTM4 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69141022; called by muse, mutect2
- MAB21L1 | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100082915; called by muse, mutect2, varscan2
- MAGT1 | c.355G>T p.V119L (on ENST00000618282 / NM_001367916.1; = p.V151L on NM_032121.5) | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100800451; called by muse, mutect2, varscan2
- MAP7D3 | c.2044G>T p.A682S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.401); catalogued as COSV60170230; called by muse, mutect2, varscan2
- MCF2 | c.2216G>T p.R739L | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV58483217; called by muse, mutect2, varscan2
- MDGA2 | c.2618C>A p.S873* (on ENST00000399232 / NM_001113498.2; = p.S575* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV62078415; called by muse, mutect2, varscan2
- MED12L | c.2180C>T p.T727I | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as rs1255538927; called by muse, mutect2, varscan2
- MICOS13 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs757092651; called by muse, mutect2, varscan2
- MICU1 | c.1373A>G p.Q458R (on ENST00000361114 / NM_001195518.2; = p.Q464R on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769314310; called by muse, mutect2, varscan2
- MOCOS | c.2402G>T p.R801L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV54344649; called by muse, mutect2, varscan2
- MRC1 | c.2769G>T p.Q923H | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV53470466; called by muse, mutect2, varscan2
- MRC1 | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 52/305 reads (17%) | catalogued as rs782352494; called by muse, mutect2, varscan2
- MRGPRX4 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1216412746; called by muse, mutect2, varscan2
- MTCL1 | c.1405G>T p.A469S (on ENST00000306329 / NM_001378206.1; = p.A109S on NM_015210.4) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV60409455; called by muse, mutect2, varscan2
- MUC16 | c.16351C>A p.P5451T | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV67442968; called by muse, mutect2, varscan2
- MUC16 | c.2344C>A p.P782T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV67476217; called by muse, mutect2, varscan2
- MUC5B | c.126C>A p.G42= | Splice Region (SNP) | VAF 8/33 reads (24%) | catalogued as rs761751705, COSV71592186; called by muse, mutect2, varscan2
- MYF6 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV57353797; called by muse, mutect2, varscan2
- MYH1 | c.2995G>C p.E999Q | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1380508250; called by muse, mutect2, varscan2
- MYH4 | c.4271G>T p.R1424M | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55124305; called by muse, mutect2, varscan2
- MYH8 | c.2171+1G>A p.X724_splice | Splice Site (SNP) | VAF 20/116 reads (17%) | catalogued as rs750636603; called by muse, mutect2, varscan2
- N4BP2 | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54700861; called by muse, mutect2, varscan2
- NCAN | c.2298C>A p.S766R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs143819093; called by muse, mutect2, varscan2
- NDN | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100086442, COSV100086481; called by muse, mutect2, varscan2
- NEB | c.5214G>T p.K1738N | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99078003; called by muse, mutect2, varscan2
- NELFA | c.1257G>C p.Q419H (on ENST00000542778; = p.Q408H on NM_005663.5) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV99043927; called by muse, mutect2, varscan2
- NEMF | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53589871, COSV53591216; called by muse, mutect2, varscan2
- NFAT5 | c.4417A>G p.I1473V | Missense Mutation (SNP) | VAF 90/151 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs753321494; called by muse, mutect2, varscan2
- NFIL3 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs748612574; called by muse, mutect2, varscan2
- NIP7 | c.246C>A p.H82Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs775560606; called by muse, mutect2, varscan2
- NKX2-4 | c.94del p.D32Tfs*127 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as COSV61085307; called by mutect2, pindel, varscan2
- NLE1 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362635267; called by muse, mutect2, varscan2
- NLGN4X | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1199804447; called by muse, mutect2, varscan2
- NLRP3 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 60/138 reads (43%) | catalogued as COSV60225054; called by muse, mutect2, varscan2
- NLRP7 | c.1946C>A p.T649N | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs1432726123; called by muse, mutect2, varscan2
- NLRP7 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751795513; called by muse, mutect2, varscan2
- NOL11 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.296); catalogued as rs757607541, COSV99475009, COSV99475345; called by muse, mutect2, varscan2
- NOS1AP | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV100722907; called by muse, mutect2, varscan2
- NPNT | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59751974; called by muse, mutect2, varscan2
- NPY1R | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.741); catalogued as COSV56716362; called by muse, mutect2, varscan2
- NTM | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 69/106 reads (65%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs145004908, COSV66205600; called by muse, mutect2, varscan2
- NTSR1 | c.634C>A p.R212S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs141293864; called by muse, mutect2, varscan2
- NUP155 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.432); catalogued as rs761630594; called by muse, mutect2, varscan2
- OCA2 | c.2200C>A p.L734M | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100668055; called by muse, mutect2, varscan2
- OR10T2 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57782038; called by muse, mutect2, varscan2
- OR2C3 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs773436526, COSV63576554; called by muse, mutect2, varscan2
- OR2M5 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs760060672; called by muse, mutect2, varscan2
- OR2T4 | c.213G>T p.L71F | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs372778082, COSV63544045; called by muse, mutect2
- OR4A16 | c.60T>G p.D20E | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59042201; called by muse, mutect2, varscan2
- OR4C15 | c.920G>A p.C307Y (on ENST00000314644; = p.C253Y on NM_001001920.2) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs143375710, COSV100116111; called by muse, mutect2, varscan2
- OR4D6 | c.266G>T p.R89M | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV55659976; called by muse, mutect2, varscan2
- OR4N5 | c.545del p.P182Hfs*17 | Frame Shift Del (DEL) | VAF 18/111 reads (16%) | catalogued as COSV61321343; called by mutect2, pindel, varscan2
- OR51B4 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV66517986; called by muse, varscan2
- OR52L1 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV59988796; called by muse, mutect2
- OR56A3 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV61569605; called by muse, mutect2, varscan2
- OR5AS1 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99046975; called by muse, mutect2, varscan2
- OR5F1 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53547100; called by muse, mutect2, varscan2
- OR5W2 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV60617889; called by muse, varscan2
- OR6B1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs200084158; called by muse, mutect2, varscan2
- OSTM1 | c.402G>T p.G134= | Splice Region (SNP) | VAF 35/108 reads (32%) | catalogued as rs756543322; called by muse, mutect2, varscan2
- OTOA | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99625601; called by muse, mutect2, varscan2
- OTOF | c.1102G>T p.G368W | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM118015; called by muse, mutect2, varscan2
- OTOG | c.3098C>T p.S1033F | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs569953721; called by muse, mutect2, varscan2
- OTUD6A | c.677C>A p.S226* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100610997; called by muse, mutect2, varscan2
- OVCH1 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs755429258; called by muse, mutect2, varscan2
- P3H2 | c.923A>G p.H308R | Missense Mutation (SNP) | VAF 102/180 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs879234801; called by muse, mutect2, varscan2
- PAH | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61020657; called by muse, mutect2, varscan2
- PAK5 | c.908C>A p.A303E | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs746868962, COSV62036542; called by muse, mutect2, varscan2
- PAPLN | c.1352G>T p.R451L (on ENST00000554301; = p.R424L on NM_173462.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV53713724; called by muse, mutect2, varscan2
- PAX3 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60586370; called by muse, mutect2, varscan2
- PBOV1 | c.257C>A p.T86K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.682); catalogued as rs755450557; called by muse, mutect2, varscan2
- PBRM1 | c.2876A>G p.H959R | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs372395774; called by muse, mutect2, varscan2
- PCDH10 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99994566; called by mutect2, varscan2
- PCDHA4 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1554123890; called by muse, mutect2, varscan2
- PCDHB16 | c.1811A>C p.Y604S | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as rs781983602; called by muse, mutect2, varscan2
- PCDHGB5 | c.2043G>T p.Q681H | Missense Mutation (SNP) | VAF 57/89 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs779918187, COSV53994863; called by muse, mutect2, varscan2
- PCOLCE | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.594); catalogued as rs755511553; called by muse, mutect2, varscan2
- PCSK2 | c.731C>A p.P244Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.292); catalogued as rs17854040; called by muse, mutect2
- PDE9A | c.497+1G>T p.X166_splice | Splice Site (SNP) | VAF 46/142 reads (32%) | catalogued as rs1336492782; called by muse, mutect2, varscan2
- PDZRN3 | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as rs1479470806, COSV55205659; called by muse, mutect2, varscan2
- PDZRN3 | c.2281G>T p.G761C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189732803; called by muse, mutect2, varscan2
- PHF2 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100823085; called by muse, mutect2
- PIK3CG | c.3071C>A p.T1024K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV63246204; called by muse, mutect2, varscan2
- PKD1L3 | c.1803C>A p.H601Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs537040106, COSV58664953; called by muse, mutect2, varscan2
- PKLR | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950947, CM971208, COSV61361113; called by muse, mutect2, varscan2
- PLB1 | c.2875G>A p.V959M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs759537881, COSV59828834; called by muse, mutect2, varscan2
- PLXNA3 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as rs368644346, COSV63754384; called by muse, mutect2
- PML | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV51446859; called by muse, mutect2, varscan2
- POPDC2 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99951120; called by muse, mutect2, varscan2
- PPFIA2 | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 47/249 reads (19%) | catalogued as COSV61059859; called by muse, mutect2, varscan2
- PPHLN1 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 26/146 reads (18%) | catalogued as rs764149372; called by muse, mutect2, varscan2
- PPP6R1 | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as rs1279021412; called by muse, mutect2, varscan2
- PRDM14 | c.1450T>A p.S484T | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.568); catalogued as rs770009110; called by muse, mutect2, varscan2
- PRF1 | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs781476866, COSV64614500; called by muse, mutect2, varscan2
- PRKACG | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs776449361; called by muse, mutect2
- PRKN | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.967); catalogued as COSV58239542, COSV58258013; called by muse, mutect2, varscan2
- PRMT9 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs145625390; called by muse, mutect2, varscan2
- PTER | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as rs747439017; called by muse, mutect2, varscan2
- PTPRD | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV61960935; called by muse, mutect2, varscan2
- PTPRK | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63888307; called by muse, mutect2, varscan2
- PTPRU | c.3418G>A p.A1140T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs916420886; called by muse, mutect2, varscan2
- PYGB | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99405393; called by muse, mutect2, varscan2
- PYGL | c.663G>T p.V221= | Splice Region (SNP) | VAF 21/51 reads (41%) | catalogued as rs370565099, COSV99368450; called by muse, mutect2, varscan2
- PYGM | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs536561941, COSV51230764; called by muse, mutect2, varscan2
- QRFPR | c.821T>C p.M274T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1483553746; called by muse, mutect2, varscan2
- RGS6 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs1465474688; called by muse, mutect2, varscan2
- RGS7 | c.846-1G>A p.X282_splice | Splice Site (SNP) | VAF 44/124 reads (35%) | catalogued as COSV58558303; called by muse, mutect2, varscan2
- RHOXF2 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as COSV101002786; called by muse, mutect2, varscan2
- RIN3 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs759963039; called by muse, mutect2, varscan2
- ROR2 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0); catalogued as COSV65244715; called by muse, mutect2, varscan2
- RTL4 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV100465881, COSV61205874; called by muse, varscan2
- RYR2 | c.7429G>T p.G2477W | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63686351; called by muse, mutect2, varscan2
- RYR2 | c.7430G>T p.G2477V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63672668; called by muse, mutect2, varscan2
- RYR2 | c.12719C>T p.T4240M | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV63714535; called by muse, varscan2
- RYR2 | c.14445C>A p.F4815L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100772105; called by muse, varscan2
- SACS | c.6905A>C p.K2302T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV101207505; called by mutect2, varscan2
- SATB2 | c.1951C>G p.Q651E | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53483325, COSV99612930; called by muse, mutect2, varscan2
- SCGB2B2 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV64857055; called by muse, mutect2, varscan2
- SCN5A | c.5168C>A p.T1723N (on ENST00000333535 / NM_198056.3; = p.T1722N on NM_000335.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.295); catalogued as rs199473300, CM097683; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- SDHAP2 | n.903A>G | Splice Region (SNP) | VAF 101/634 reads (16%) | catalogued as rs764183000; called by muse, varscan2
- SEC24B | c.2653G>T p.A885S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.639); catalogued as rs373550185; called by muse, mutect2, varscan2
- SEMA3F | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as rs752403483; called by muse, mutect2, varscan2
- SEMA6D | c.2585A>T p.K862M (on ENST00000316364 / NM_153618.2; = p.K800M on NM_020858.2) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as COSV60375793; called by muse, mutect2, varscan2
- SERPINA4 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs1278033042, COSV54069426; called by muse, mutect2, varscan2
- SERPING1 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1362220560; called by muse, mutect2, varscan2
- SHLD2 | c.1583G>A p.S528N | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs756184116; called by muse, mutect2, varscan2
- SHOX | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM011486, COSV61862044; called by muse, mutect2, varscan2
- SHPRH | c.3833G>T p.G1278V (on ENST00000275233 / NM_001042683.3; = p.G1282V on NM_173082.3) | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768982387; called by muse, mutect2, varscan2
- SLC15A2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1286522851, COSV55200884; called by muse, mutect2, varscan2
- SLC2A2 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 94/183 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.044); catalogued as rs748052042; called by muse, mutect2, varscan2
- SLC35A3 | c.*560G>T | Splice Region (SNP) | VAF 10/20 reads (50%) | catalogued as COSV64516556; called by muse, mutect2, varscan2
- SLC37A1 | c.1586+1G>T p.X529_splice | Splice Site (SNP) | VAF 18/61 reads (30%) | catalogued as COSV61401216; called by muse, mutect2, varscan2
- SLC44A5 | c.1641G>T p.L547F | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs764447076; called by muse, mutect2, varscan2
- SLC45A2 | c.1036G>T p.V346L | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1350569256; called by muse, mutect2, varscan2
- SLC46A3 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs181221290; called by muse, mutect2, varscan2
- SLC5A5 | c.1524C>G p.P508= | Splice Region (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99714700; called by muse, mutect2, varscan2
- SLC9A3 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM1512085; called by muse, mutect2, varscan2
- SLCO1B1 | c.915G>C p.K305N | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV57016831; called by muse, mutect2, varscan2
- SLITRK2 | c.64C>A p.R22S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.501); catalogued as COSV100158069, COSV59424087; called by muse, mutect2, varscan2
- SLITRK2 | c.1579C>A p.Q527K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.25); catalogued as COSV59425792; called by muse, mutect2
- SLITRK3 | c.2313A>T p.E771D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53849550; called by muse, mutect2, varscan2
- SMAP1 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100390609; called by muse, mutect2, varscan2
- SMARCA4 | c.3485G>C p.G1162A | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60811919; called by muse, mutect2, varscan2
- SMOC2 | c.187C>A p.R63S | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.56); catalogued as COSV62440425; called by muse, mutect2, varscan2
- SPTA1 | c.2898G>T p.Q966H | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV63750156; called by muse, varscan2
- SPTB | c.6277G>A p.E2093K | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.216); catalogued as rs1328912901; called by muse, mutect2, varscan2
- SPTB | c.3172G>T p.G1058W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV67631534; called by muse, mutect2, varscan2
- SPTBN5 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV58027153; called by muse, mutect2, varscan2
- SSH2 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV104393186; called by muse, mutect2, varscan2
- STON2 | c.2150G>T p.R717L (on ENST00000649389 / NM_001366849.2; = p.R660L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50842334; called by muse, mutect2, varscan2
- STXBP5 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.313); catalogued as COSV51648713; called by muse, mutect2, varscan2
- STXBP5 | c.431G>T p.R144M | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51648727; called by muse, mutect2, varscan2
- SULT1E1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV56947926; called by muse, mutect2, varscan2
- SYCP3 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57149249; called by muse, mutect2, varscan2
- SYK | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV65327255; called by muse, mutect2, varscan2
- SYNE2 | c.10303G>T p.D3435Y | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs931738357; called by muse, mutect2, varscan2
- SYT5 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1176712345; called by muse, mutect2, varscan2
- SZT2 | c.5168C>T p.A1723V (on ENST00000634258 / NM_001365999.1; = p.A1666V on NM_015284.4) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1473283422; called by muse, mutect2, varscan2
- TANC1 | c.3565G>T p.G1189C | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755826547; called by muse, mutect2, varscan2
- TBX5 | c.215C>G p.T72R | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM157843; called by muse, mutect2, varscan2
- TBXT | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51617503; called by muse, mutect2, varscan2
- TCF4 | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100610426; called by muse, mutect2, varscan2
- TENM1 | c.1288C>A p.L430M | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV100949418; called by muse, mutect2, varscan2
- TEPSIN | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs143078481; called by muse, mutect2
- TEX13C | c.1049C>A p.P350Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV70114374; called by muse, mutect2, varscan2
- TEX26 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs754014952; called by muse, mutect2, varscan2
- TEX47 | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 110/188 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs767449422; called by muse, mutect2, varscan2
- TFAP2B | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV99539524; called by muse, mutect2, varscan2
- TFEC | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55405083; called by muse, mutect2, varscan2
- TMC3 | c.1622G>A p.W541* | Nonsense Mutation (SNP) | VAF 39/85 reads (46%) | catalogued as rs1344982621; called by muse, mutect2, varscan2
- TMC5 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV66867996; called by muse, mutect2, varscan2
- TMEM121B | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs768066373, COSV100083413; called by muse, mutect2, varscan2
- TMEM132B | c.854C>A p.S285* | Nonsense Mutation (SNP) | VAF 16/109 reads (15%) | catalogued as COSV54747299; called by muse, mutect2, varscan2
- TMEM132C | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1287005938, COSV59434010; called by muse, mutect2, varscan2
- TMEM229A | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV71900224; called by muse, mutect2, varscan2
- TMEM260 | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376435235; called by muse, mutect2, varscan2
- TMEM68 | c.198C>A p.H66Q | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1184240617; called by muse, mutect2, varscan2
- TNN | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.071); catalogued as COSV53429565; called by muse, mutect2
- TPP2 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.251); catalogued as COSV65754005; called by muse, mutect2, varscan2
- TRAF4 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs754546702; called by muse, mutect2, varscan2
- TRAM1 | c.485+1G>T p.X162_splice | Splice Site (SNP) | VAF 16/100 reads (16%) | catalogued as COSV99140787; called by muse, mutect2, varscan2
- TRGC2 | c.429T>A p.D143E | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.198); catalogued as rs1218384473; called by muse, mutect2, varscan2
- TRPA1 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs759879377, COSV51566671; called by muse, mutect2, varscan2
- TRPA1 | c.690G>C p.L230F | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV51559581; called by muse, mutect2, varscan2
- TSHR | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV99992580; called by muse, mutect2, varscan2
- TSSC4 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770569974; called by muse, mutect2, varscan2
- TTN | c.34847C>A p.A11616E (on ENST00000591111; = p.A10689E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | PolyPhen benign (0); catalogued as COSV60234178; called by muse, mutect2, varscan2
- TUBD1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1444280305; called by muse, mutect2, varscan2
- TYW1B | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782046046, COSV101444277; called by muse, mutect2, varscan2
- UACA | c.498C>T p.D166= | Splice Region (SNP) | VAF 20/74 reads (27%) | catalogued as rs575135370; called by muse, mutect2, varscan2
- UBE2D1 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 51/89 reads (57%) | catalogued as COSV64219049; called by muse, mutect2, varscan2
- UGT2A3 | c.1349A>C p.Q450P | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52359634; called by muse, mutect2, varscan2
- UGT2A3 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV52362265; called by muse, mutect2, varscan2
- UNC45A | c.2313C>G p.I771M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs780133821; called by muse, mutect2, varscan2
- UNC5B | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.714); catalogued as rs1214447988, COSV58975215; called by muse, mutect2, varscan2
- UNC80 | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55892952; called by muse, mutect2, varscan2
- UNC80 | c.1874C>A p.S625Y | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55905918; called by muse, mutect2, varscan2
- UNC80 | c.3754G>T p.G1252* | Nonsense Mutation (SNP) | VAF 52/176 reads (30%) | catalogued as COSV55888455; called by muse, mutect2, varscan2
- UNK | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53139266; called by muse, mutect2, varscan2
- USP10 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs758198904; called by muse, mutect2, varscan2
- USP17L7 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as rs773257019; called by muse, mutect2, varscan2
- USP34 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs1317764083; called by muse, mutect2, varscan2
- VPS50 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs748857889; called by muse, mutect2, varscan2
- VWA3A | c.2432C>T p.T811I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as COSV55393260; called by muse, mutect2, varscan2
- WDR72 | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64742229; called by muse, mutect2, varscan2
- WDR87 | c.6829G>T p.E2277* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs1016901037; called by muse, mutect2, varscan2
- YTHDC2 | c.1613C>G p.S538* | Nonsense Mutation (SNP) | VAF 43/79 reads (54%) | catalogued as COSV99362977, COSV99363041; called by muse, mutect2, varscan2
- ZFAND4 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs768754689; called by muse, mutect2, varscan2
- ZFHX4 | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.623); catalogued as COSV50481490, COSV51477651; called by muse, varscan2
- ZFHX4 | c.7718C>T p.T2573M | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs767006421; called by muse, mutect2, varscan2
- ZFP62 | c.1657C>G p.R553G (on ENST00000502412 / NM_001377944.1; = p.R520G on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs897936540, COSV100772736; called by muse, mutect2, varscan2
- ZFPM2 | c.1705C>A p.H569N | Missense Mutation (SNP) | VAF 117/303 reads (39%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.995); catalogued as COSV65873261; called by muse, mutect2, varscan2
- ZKSCAN1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs752416389; called by muse, mutect2, varscan2
- ZMYM4 | c.99G>T p.M33I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100111193; called by muse, mutect2, varscan2
- ZNF112 | c.2509G>T p.V837L (on ENST00000337401 / NM_001083335.2; = p.V831L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV100495602; called by muse, mutect2, varscan2
- ZNF197 | c.2048G>T p.C683F | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998106665; called by muse, mutect2, varscan2
- ZNF208 | c.3334C>A p.P1112T | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769480170; called by muse, mutect2, varscan2
- ZNF208 | c.2420G>T p.C807F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV68107829; called by muse, varscan2
- ZNF333 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as rs1166675099; called by muse, mutect2, varscan2
- ZNF492 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as rs1354273709; called by mutect2, varscan2
- ZNF536 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV62819722; called by muse, mutect2, varscan2
- ZNF711 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 52/138 reads (38%) | catalogued as COSV52157879; called by muse, mutect2, varscan2
- ZNF729 | c.1997G>T p.S666I | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.853); catalogued as COSV62605578; called by muse, varscan2
- ZP4 | c.1109C>A p.T370K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100850797; called by muse, varscan2
- AASS | c.2721A>G p.I907M | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ABCA12 | c.1387C>G p.L463V (on ENST00000272895 / NM_173076.3; = p.L145V on NM_015657.3) | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ABCA13 | c.7958G>A p.R2653K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- ABCA4 | c.6474G>T p.K2158N | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ABCA6 | c.4764G>C p.E1588D | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA8 | c.2457A>T p.E819D | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ABCB9 | c.1332C>G p.N444K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ABCC9 | c.651del p.Q217Hfs*4 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- ABCG1 | c.735-2A>T p.X245_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- AC011455.2 | c.1486A>T p.T496S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2
- AC244258.1 | n.624-2A>T | Splice Site (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- ACSM2A | c.1377G>T p.M459I (on ENST00000219054; = p.M380I on NM_001308169.2) | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- ACSM5 | c.1657-6C>G | Splice Region (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- ACTR3B | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ACVR1 | c.455G>C p.R152P | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- ADAM33 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ADAMTS1 | c.2621G>T p.W874L | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS17 | c.424A>T p.S142C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- ADAMTS20 | c.2711G>T p.C904F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS20 | c.2710T>C p.C904R | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS20 | c.2551G>T p.D851Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS4 | c.2335C>A p.Q779K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY10 | c.3955G>A p.G1319S | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADCY2 | c.2746_2748delinsTT p.N917Tfs*35 | Frame Shift Del (DEL) | VAF 34/144 reads (24%) | called by pindel, varscan2*
- ADCY7 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADCY8 | c.2721G>T p.M907I | Missense Mutation (SNP) | VAF 150/215 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ADGB | c.613-1G>A p.X205_splice | Splice Site (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- ADGRD1 | c.2436+7C>T | Splice Region (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2
- ADGRD2 | c.2298G>T p.M766I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ADRA2C | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AFF2 | c.29G>T p.W10L | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, varscan2
- AFF3 | c.129T>A p.D43E | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AGBL2 | c.1891T>A p.S631T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AGMO | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGPAT4 | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 91/185 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AGPS | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGTR1 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 95/155 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- AHNAK2 | c.12562G>T p.A4188S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- AK3 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- AKAP6 | c.1942del p.E648Kfs*3 | Frame Shift Del (DEL) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- AKR1A1 | c.356+2T>G p.X119_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- AKR1B1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- AKR1C3 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AL021368.4 | n.219+1G>T | Splice Site (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- AL096814.1 | c.205A>G p.K69E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- AL592490.1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- ALB | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2
- ALOX15 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALOX5 | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALOXE3 | c.2059C>T p.Q687* | Nonsense Mutation (SNP) | VAF 38/66 reads (58%) | called by muse, mutect2, varscan2
- ALPK2 | c.1640A>T p.K547M | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ALX1 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ANGPT4 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKEF1 | c.2248G>C p.V750L | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ANKRD17 | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- ANKRD30B | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- ANKRD30B | c.1480G>T p.G494W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); called by muse, varscan2
- ANKRD31 | c.5096T>A p.I1699K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ANKRD34C | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ANKRD42 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ANKUB1 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ANO7 | c.110G>C p.R37T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AOC1 | c.82dup p.R28Kfs*61 | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- AP002512.3 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- APCS | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOB | c.6361C>A p.Q2121K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- APOB | c.3664A>G p.T1222A | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- AR | c.990C>A p.S330R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.474); called by muse, varscan2
- ARFGEF1 | c.735A>T p.Q245H | Missense Mutation (SNP) | VAF 86/257 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP42 | c.2561G>T p.W854L | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARHGEF10 | c.2463-1G>T p.X821_splice (on ENST00000398564; = p.X796_splice on NM_014629.4) | Splice Site (SNP) | VAF 30/106 reads (28%) | called by muse, varscan2
- ARHGEF10 | c.3471A>T p.P1157= (on ENST00000398564; = p.P1132= on NM_014629.4) | Splice Region (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.2088G>T p.K696N | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF4 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ARID1A | c.6711_6712del p.L2238Afs*39 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by pindel, varscan2
- ARMH4 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- ARR3 | c.768-1G>A p.X256_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2
- ATF6 | c.1615G>T p.G539W | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP10A | c.2953A>G p.K985E | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.017); called by muse, mutect2
- ATP2B3 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ATP6AP1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ATP7A | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATRNL1 | c.929C>A p.A310E | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- ATRX | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AWAT1 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 85/247 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- AZGP1 | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, varscan2
- BAIAP3 | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- BAZ2A | c.4973G>A p.C1658Y | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- BAZ2A | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BCHE | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL2L12 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- BCORL1 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- BICC1 | c.2262dup p.T755Hfs*11 | Frame Shift Ins (INS) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- BIRC6 | c.5917G>C p.A1973P | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- BMT2 | c.686C>G p.P229R | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- BOD1L1 | c.7700C>A p.T2567N | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BOD1L1 | c.4838G>T p.G1613V | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BPIFC | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BPNT1 | c.340G>T p.V114F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- BRCC3 | c.860T>A p.L287* | Nonsense Mutation (SNP) | VAF 69/189 reads (37%) | called by muse, mutect2, varscan2
- BTK | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C11orf87 | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- C12orf50 | c.1055G>C p.R352P | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- C16orf89 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- C19orf84 | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C1QTNF4 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- C1orf194 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C1orf94 | c.863C>A p.P288Q (on ENST00000488417 / NM_001134734.2; = p.P98Q on NM_032884.5) | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- C8orf34 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- CA5A | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CA7 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1S | c.2536G>T p.E846* | Nonsense Mutation (SNP) | VAF 57/146 reads (39%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.1523C>A p.P508H | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CACNA2D4 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNG6 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- CADM3 | c.636C>G p.N212K (on ENST00000368125 / NM_001127173.3; = p.N246K on NM_021189.5) | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, varscan2
- CALCRL | c.436A>T p.I146L | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CAPN1 | c.1942G>C p.G648R | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARMIL1 | c.592del p.D198Ifs*10 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- CCDC14 | c.2594C>G p.S865C (on ENST00000488653; = p.S817C on NM_022757.5) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CCDC168 | c.16492G>C p.E5498Q | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CCDC168 | c.15004A>G p.K5002E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CCDC168 | c.2345A>G p.E782G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CCDC7 | c.2396T>A p.V799E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, varscan2
- CCKAR | c.773C>A p.T258N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCL17 | c.119del p.G40Efs*8 | Frame Shift Del (DEL) | VAF 37/90 reads (41%) | called by mutect2, pindel, varscan2
- CCR6 | c.941del p.V314Gfs*15 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | called by mutect2, pindel, varscan2
- CCS | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CD99L2 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH12 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH2 | c.2515-1G>T p.X839_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
- CDH2 | c.443G>T p.S148I | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH23 | c.2279G>T p.G760V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- CDK5RAP3 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CDK8 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEACAM20 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CELSR2 | c.7562G>T p.W2521L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPE | c.5523G>T p.E1841D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CENPF | c.3974G>T p.R1325M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CENPJ | c.1678A>T p.K560* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- CENPS | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CEP295NL | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CERS3 | c.427T>A p.L143I | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CES2 | c.982G>C p.A328P | Missense Mutation (SNP) | VAF 73/113 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CFAP46 | c.4582G>T p.V1528L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2
- CFAP47 | c.9450G>T p.K3150N | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CFTR | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- CHAT | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHGB | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, varscan2
- CHIT1 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CHL1 | c.1282A>T p.K428* (on ENST00000397491 / NM_001253387.1; = p.K444* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- CHM | c.1241G>T p.R414I | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CHRNA4 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- CLCN5 | c.1713A>T p.E571D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLEC12B | c.409+1G>T p.X137_splice | Splice Site (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- CLEC4E | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CLIC5 | c.541-1G>T p.X181_splice (on ENST00000185206 / NM_001370649.1; = p.X22_splice on NM_016929.5) | Splice Site (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- CLIP4 | c.2104G>T p.D702Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CLTCL1 | c.4648G>T p.A1550S (on ENST00000427926 / NM_007098.4; = p.A1493S on NM_001835.4) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CLVS1 | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CMC1 | c.128A>T p.K43M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CMTM2 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CNBD1 | c.887A>T p.K296M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CNGB3 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 87/293 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNGB3 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CNOT1 | c.5029G>T p.D1677Y | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CNTLN | c.62G>T p.R21M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CNTN2 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, varscan2
- CNTN5 | c.2338G>T p.V780L | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CNTNAP2 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- COG4 | c.1297A>T p.R433W | Missense Mutation (SNP) | VAF 98/176 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL11A1 | c.2131C>A p.P711T | Missense Mutation (SNP) | VAF 94/168 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL15A1 | c.2464G>A p.V822M | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL17A1 | c.986C>A p.T329N | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- COL6A2 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A2 | c.1459G>T p.G487* | Nonsense Mutation (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- COL6A3 | c.5198C>A p.P1733H | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- COL6A3 | c.67A>T p.T23S | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CPNE3 | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CPSF1 | c.1243-6T>A | Splice Region (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- CRB2 | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CREBRF | c.1035G>C p.L345F | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CRISPLD1 | c.989A>T p.Y330F | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRLF3 | c.616T>C p.F206L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.12); called by muse, mutect2
- CRNKL1 | c.1766T>A p.L589Q | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CRYBG1 | c.5205A>T p.K1735N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CSF2RA | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CSMD2 | c.8866G>T p.G2956W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.1144G>T p.V382F | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, varscan2
- CSMD3 | c.547G>T p.V183F | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- CST8 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTNNA2 | c.1469A>T p.E490V | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CTNNAL1 | c.1883A>T p.E628V | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTSL | c.396+1G>T p.X132_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- CUBN | c.3647C>A p.P1216Q | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CUX1 | c.473A>T p.E158V (on ENST00000292535 / NM_181552.4; = p.E169V on NM_001913.5) | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CWC22 | c.2093G>T p.S698I | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- CWC25 | c.547A>T p.K183* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- CYB5R4 | c.1173A>C p.E391D | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CYB5R4 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CYFIP1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- CYSLTR2 | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- CYTH3 | c.661A>T p.M221L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DCAF15 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DCC | c.2959G>C p.D987H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- DCDC1 | c.2854G>T p.V952F (on ENST00000597505 / NM_001367979.1; = p.V59F on NM_020869.3) | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX60 | c.4299G>T p.M1433I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX60L | c.4363+1G>T p.X1455_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- DGKB | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGKZ | c.2450G>T p.R817L (on ENST00000454345 / NM_001105540.2; = p.R629L on NM_003646.4) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- DHTKD1 | c.305C>A p.T102K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.463); called by muse, mutect2
- DHX38 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 88/156 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- DHX38 | c.1449G>T p.K483N | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DLG3 | c.1480G>T p.G494W (on ENST00000374360 / NM_021120.4; = p.G157W on NM_020730.3) | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLG4 | c.381G>T p.E127D (on ENST00000399506 / NM_001321075.3; = p.E170D on NM_001365.4) | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.65); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DLGAP3 | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DMD | c.9023A>T p.Q3008L | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- DMRTC2 | c.197G>T p.C66F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNA2 | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAAF3 | c.822G>T p.W274C (on ENST00000524407 / NM_001256715.2; = p.W321C on NM_178837.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAAF3 | c.821G>T p.W274L (on ENST00000524407 / NM_001256715.2; = p.W321L on NM_178837.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH10 | c.8295G>T p.L2765= (on ENST00000409039; = p.L2704= on NM_207437.3) | Splice Region (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- DNAH11 | c.11471C>A p.T3824N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- DNAH6 | c.10756G>T p.V3586F | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- DNAI3 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAJA2 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 39/66 reads (59%) | called by muse, mutect2, varscan2
- DOC2B | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK2 | c.3776C>A p.A1259E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DOHH | c.56A>G p.Q19R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOK6 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- DPY30 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DPYSL5 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DRD5 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRD5 | c.1259C>G p.P420R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DRP2 | c.2684C>A p.P895Q | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- DSCAML1 | c.3220C>A p.L1074M (on ENST00000321322; = p.L1014M on NM_020693.4) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DSG3 | c.299T>C p.F100S | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSP | c.6766G>T p.G2256C | Missense Mutation (SNP) | VAF 135/219 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTNA | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUOX1 | c.3824T>C p.I1275T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- DZIP3 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ECPAS | c.3512G>T p.R1171L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF1A2 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EFCAB6 | c.4308G>T p.W1436C | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGFLAM | c.1894C>A p.L632I | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EGR4 | c.344C>A p.A115E (on ENST00000545030; = p.A12E on NM_001965.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- EIF4A3 | c.1049T>A p.I350N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EML5 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENOX2 | c.461T>A p.I154N (on ENST00000338144 / NM_001382520.1; = p.I125N on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ENTPD7 | c.329A>T p.H110L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- EPM2AIP1 | c.1276A>T p.I426F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- EPPK1 | c.2354G>T p.C785F | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBB3 | c.437dup p.V147Cfs*4 | Frame Shift Ins (INS) | VAF 37/124 reads (30%) | called by mutect2, pindel, varscan2
- ERVH48-1 | c.281T>A p.V94E | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ESRRG | c.854A>G p.H285R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- EVC2 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EYS | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EZH2 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- F2 | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- F2 | c.1350C>A p.H450Q | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F8 | c.3110C>A p.P1037Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- FAM120C | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, varscan2
- FAM122B | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM135B | c.2518C>A p.Q840K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAM172A | c.944C>G p.T315S | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FAM200B | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FAM205A | c.3874C>A p.P1292T | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- FAM47C | c.1985G>C p.R662P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, varscan2
- FAM53C | c.1074G>C p.E358D | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- FAM71D | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM71F1 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM90A1 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM98B | c.217G>T p.G73* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- FAT4 | c.5442dup p.R1815Sfs*3 | Frame Shift Ins (INS) | VAF 39/163 reads (24%) | called by mutect2, pindel, varscan2
- FAT4 | c.6044A>C p.N2015T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- FAT4 | c.7652C>A p.T2551K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FAT4 | c.14623G>T p.V4875F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FBN2 | c.8715G>T p.M2905I | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGD1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- FGD1 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FILIP1L | c.1452C>A p.F484L (on ENST00000354552 / NM_182909.3; = p.F244L on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/119 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.11056G>T p.G3686W | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLRT3 | c.1642G>T p.V548L | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FMN1 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- FOLH1 | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXD4L4 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FREM3 | c.2691C>A p.N897K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FRG2C | c.256+1G>T p.X86_splice | Splice Site (SNP) | VAF 107/457 reads (23%) | called by muse, varscan2
- FSHR | c.1847C>A p.P616H | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FYB1 | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FZD4 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- G6PC | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALC | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALNT2 | c.872G>T p.R291M | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- GALNTL6 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATB | c.328-1G>C p.X110_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- GDF10 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- GIT2 | c.767G>T p.S256I (on ENST00000355312 / NM_057169.5; = p.S258I on NM_014776.5) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- GLG1 | c.2437-2A>T p.X813_splice | Splice Site (SNP) | VAF 43/75 reads (57%) | called by muse, mutect2, varscan2
- GLRA1 | c.799T>C p.W267R | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLUD1 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GNAS | c.718+3A>T | Splice Region (SNP) | VAF 93/260 reads (36%) | called by muse, mutect2, varscan2
- GNE | c.637G>T p.G213C (on ENST00000396594 / NM_001128227.3; = p.G182C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA1 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.039); called by muse, mutect2
- GOLGA8M | c.1882C>A p.P628T | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- GOLIM4 | c.262+2del p.X88_splice | Splice Site (DEL) | VAF 34/82 reads (41%) | called by mutect2, pindel*, varscan2
- GON4L | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 57/244 reads (23%) | called by muse, mutect2, varscan2
- GON4L | c.831G>T p.L277F | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPM6A | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GPR101 | c.1179C>A p.Y393* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- GPR12 | c.535T>G p.W179G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GPR137B | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, varscan2
- GPR158 | c.2107G>T p.A703S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- GPR52 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GPR55 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- GPR78 | c.496C>G p.R166G | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPRASP1 | c.2969G>C p.G990A | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM3 | c.2462C>A p.P821H | Missense Mutation (SNP) | VAF 134/245 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRM8 | c.927T>A p.D309E | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GRM8 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 59/276 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GRWD1 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSK3B | c.613A>T p.K205* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- GTPBP10 | c.928A>C p.M310L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- GUSB | c.913-5C>G | Splice Region (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- H2AC11 | c.119A>T p.Y40F | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- HAS1 | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCN1 | c.840A>T p.Q280H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- HDAC2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HDAC9 | c.1512A>T p.E504D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HELB | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HERC2 | c.4371A>T p.L1457F | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HIC2 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- HIF1A | c.947G>C p.W316S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIRA | c.1902G>T p.E634D | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIVEP2 | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HLA-C | c.617_618del p.A206Gfs*14 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- HMCN1 | c.339+1G>T p.X113_splice | Splice Site (SNP) | VAF 78/212 reads (37%) | called by muse, mutect2, varscan2
- HMCN2 | c.4701G>C p.K1567N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HMGN5 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HNRNPK | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HNRNPUL1 | c.649A>T p.N217Y | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HOXC9 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HPD | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- HSPA13 | c.376A>C p.K126Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- HTR3E | c.490C>G p.L164V (on ENST00000415389 / NM_001256613.1; = p.L179V on NM_182589.2) | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- HTR5A | c.853del p.L285Sfs*52 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by pindel, varscan2
- HUWE1 | c.5534C>G p.A1845G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IFI44L | c.1024G>T p.V342F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- IFNA10 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IGBP1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- IGBP1 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.295); called by muse, mutect2, varscan2
1,141 further variants in this file (542 protein-altering or splice-affecting, 380 silent, 219 other) are not listed here.
